Somatic mutation profile of tumor specimen 0DTFRS from CCDI case PBCJCP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,977 days).
Specimen 0DTFRS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84b31893-841a-44fa-9eef-39e4442d1932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTFRW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/699851e2-3d80-489c-a34a-eea6b0995d45

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF6 | c.228A>G p.P76= | Silent (SNP) | VAF 36/1024 reads (4%) | catalogued as rs1281823901; called by muse, mutect2
- SLURP1 | c.240C>T p.T80= | Silent (SNP) | VAF 33/607 reads (5%) | catalogued as rs761340156; called by muse, mutect2
